Somatic mutation profile of tumor specimen C3N-01808-02 (aliquot CPT0089460009) from CPTAC case C3N-01808, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 47.7 years (17,422 days).
Specimen C3N-01808-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0c7dbad-b19f-444c-a95e-3a3fb2f9e752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01808-31 (Blood Derived Normal), aliquot CPT0091340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/659660f8-1e35-4c5b-a708-7464d03a60ae

The open-access MAF lists 51 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 15, Intron 7, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf53 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs750995204; called by muse, mutect2, varscan2
- COL28A1 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372891867; called by muse, mutect2, varscan2
- GAS2L2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555599927; called by muse, mutect2
- LRP5 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV53714295; called by muse, mutect2, varscan2
- MAP1A | c.6226C>T p.P2076S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs773400796; called by muse, mutect2, varscan2
- NAALAD2 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs750672339; called by muse, mutect2, varscan2
- SBNO1 | c.1022T>A p.L341* (on ENST00000420886; = p.L340* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99928875; called by muse, mutect2, varscan2
- ADAD1 | c.973T>G p.Y325D | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS10 | c.698_702delinsC p.R233Pfs*17 | Frame Shift Del (DEL) | VAF 70/318 reads (22%) | called by pindel, varscan2*
- ADGRV1 | c.15651T>A p.H5217Q | Missense Mutation (SNP) | VAF 155/456 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATF7IP2 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, varscan2
- C12orf29 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEMIP | c.2502G>C p.K834N | Missense Mutation (SNP) | VAF 162/502 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FEV | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FYCO1 | c.3610T>C p.Y1204H | Missense Mutation (SNP) | VAF 152/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABBR1 | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.6841_6842del p.E2281Ifs*8 | Frame Shift Del (DEL) | VAF 84/290 reads (29%) | called by mutect2, pindel, varscan2
- IFIT1B | c.867C>A p.H289Q | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- KCNU1 | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KRT37 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NLRC5 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2
- OBSCN | c.21179C>G p.S7060C | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARP4 | c.4555C>T p.Q1519* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- PSMB10 | c.57-1G>T p.X19_splice | Splice Site (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- SGK1 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.6617A>C p.E2206A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.294); called by muse, mutect2
- TMEM63C | c.637A>T p.R213W | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- UBC | c.146del p.Q49Rfs*33 | Frame Shift Del (DEL) | VAF 109/416 reads (26%) | called by mutect2, pindel, varscan2
- UTP14A | c.1349-7_1349delinsTTTTTTTT p.X450_splice | Splice Site (ONP) | VAF 4/39 reads (10%) | called by mutect2*, pindel
- ACRBP | c.678G>A p.Q226= | Silent (SNP) | VAF 57/174 reads (33%) | called by muse, mutect2, varscan2
- CYB5R3 | c.664C>T p.L222= | Silent (SNP) | VAF 66/271 reads (24%) | called by muse, mutect2, varscan2
- CYB5R3 | c.663G>A p.E221= | Silent (SNP) | VAF 68/273 reads (25%) | called by muse, mutect2, varscan2
- DCST1 | c.675C>T p.R225= | Silent (SNP) | VAF 107/347 reads (31%) | called by muse, mutect2, varscan2
- FERMT2 | c.789T>C p.D263= | Silent (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- FGB | c.7A>C p.R3= | Silent (SNP) | VAF 63/200 reads (32%) | catalogued as COSV57418609; called by muse, mutect2, varscan2
- GTPBP4 | c.306C>G p.A102= | Silent (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.29109C>T p.T9703= | Silent (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- NUTM2B | c.75G>A p.R25= | Silent (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- PCK1 | c.1194T>G p.P398= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as COSV60128370; called by muse, mutect2, varscan2
- RTCB | c.1248A>G p.E416= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs760170995; called by muse, mutect2, varscan2
- SLC25A47 | c.78G>A p.R26= | Silent (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- TBC1D12 | c.1302G>A p.K434= | Silent (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- TP73 | c.1473C>T p.P491= | Silent (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- ZIC1 | c.417C>T p.G139= | Silent (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- COLEC11 | c.328+995G>A | Intron (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- FYB1 | c.1360-141T>G | Intron (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- FYB1 | c.1360-142G>A | Intron (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- GABRE | c.784+1225A>G | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- MFAP5 | c.410-339A>G | Intron (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- TTC38 | c.615+1448A>T | Intron (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- ZFAND1 | c.480+5094T>C | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
